Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1L0, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1L0-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

Specimens Submitted:

- 1: SP: Intra-abdominal liposarcoma
- 2: SP: Mesenteric mass

DIAGNOSIS:

- 1) SOFT TISSUE, INTRA-ABDOMINAL; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA.
- TUMOR SIZE: 27 X 25 X 18 CM.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND IS COMPOSED OF A FIBROSARCOMA-LIKE GROWTH PATTERN. WELL-DIFFERENTIATED COMPONENT CONSISTS OF LESS THAN 5% OF THE MASS.
- TUMOR SHOWS FOCAL NECROSIS (GROSSLY ESTIMATED AS 25% OF THE MASS).
- TUMOR FOCALLY EXTENDS TO THE UNDESIGNATED INKED MARGIN.
- GREATER OMENTUM WITHOUT SIGNIFICANT CHANGES.
- 2) SOFT TISSUE, MESENTERIC MASS; RESECTION:
- WELL-DIFFERENTIATED LIPOSARCOMA.
- TUMOR SIZE: 3.2 X 2.2 X 0.5 CM.
- TUMOR EXTENDS TO THE INKED SURFACE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description

- 1). The specimen is received in fresh state, labeled as "intraabdominal liposarcoma", and it consists of an unoriented lobulated mass surrounded by

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & mixed Tumo

Page 2 of 2

grossly intact pseudocapsule measuring 27 x 25 x 18cm. A 35x69x1cm grossly unremarkable greater omentum is attached. The specimen surface is inked. Sectioning reveals tan-yellow fleshy mass with approximately 35% central necrosis. Small portion (less than 5 %) of the tumor at the periphery appears frankly adipose in nature. The specimen is photographed. TPS is taken.

Summary of sections: M margins

N - necrosis

F fatty area of tumor

T solid fleshy area of tumor

OM omentum

2). The specimen is received in formalin, labeled "mesenteric mass" and consists of a fragment of lobulated fibroadipose tissue measuring 3.2 x 2.2 x 0.5 cm. The specimen is inked in black and serially sectioned revealing a yellow-white cut surface. A thin fibrous lining is present on the external surface. The specimen is representatively submitted.

Summary of sections:

U- undesignated

Summary of Sections:

Part 1: SP: Intra-abdominal liposarcoma

Block	Sect.	Site	PCs
2	f		2
4	m		4
4	n		4
1	om		1
17	t		17

Part 2: SP: Mesenteric mass

Block	Sect.	Site	PCs
3	u		3

**** End of Report ****

Source: NCI Genomic Data Commons file c641c4d4-b642-48d1-998a-a9e25094dc71 (TCGA-DX-A1L0.A53F7252-401B-4C74-A318-2C31A4CF5927.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).